Somatic mutation profile of tumor specimen ALCH-B1ZQ-TTP1-A (aliquot ALCH-B1ZQ-TTP1-A-1-0-D-A76I-36) from ALCHEMIST case ALCH-B1ZQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 67.7 years (24,728 days).
Specimen ALCH-B1ZQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36910761-7b0a-445d-9a00-50f2f48bcfb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1ZQ-NB1-A (Blood Derived Normal), aliquot ALCH-B1ZQ-NB1-A-1-0-D-A76I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6116ff9d-6e29-412d-96cc-a193bed222cf

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEMA5A | c.935A>T p.N312I | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778813940; called by muse, mutect2
- KBTBD2 | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 16/514 reads (3%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2
- SLC17A4 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 15/505 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2
- TRIO | c.2685C>T p.A895= | Silent (SNP) | VAF 23/397 reads (6%) | catalogued as rs760667902; called by muse, mutect2
- SLC2A4 | c.34-43T>C | Intron (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
